Somatic mutation profile of tumor specimen MMRF_1535_1_BM_CD138pos (aliquot MMRF_1535_1_BM_CD138pos_T2_KBS5U_L05368) from MMRF case MMRF_1535, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.3 years (23,848 days).
Specimen MMRF_1535_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af04ad7f-a9b0-4ecd-ac52-75b6d66690cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1535_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1535_1_PB_Whole_C3_KBS5U_L05354; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d582613-b971-45e9-b22a-e4e848819e18

The open-access MAF lists 88 somatic variants for this specimen: 33 protein-altering or splice-affecting, 13 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, 3'UTR 17, Intron 15, Silent 13, 5'UTR 3, RNA 3, 5'Flank 2, Nonsense Mutation 2, 3'Flank 2, In Frame Del 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2339G>A p.R780K | Missense Mutation (SNP) | VAF 3/20 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705570, COSV66707409; called by muse, mutect2
- ARNT2 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs768601519, COSV57582940; called by muse, mutect2, varscan2
- C4orf50 | c.629C>T p.A210V (on ENST00000324058; = p.A1442V on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs749562220; called by muse, mutect2, varscan2
- EPHA3 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 22/55 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as COSV60726282; called by muse, mutect2, varscan2
- EXOC4 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.989); catalogued as rs919867909, COSV54091755; called by muse, mutect2, varscan2
- GPR31 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV64762110; called by muse, mutect2, varscan2
- IFIT5 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs764488969, COSV65655818; called by muse, mutect2, varscan2
- IGHV2-70D | c.305C>G p.T102R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs1310540287; called by muse, varscan2
- IGHV5-51 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.189); catalogued as rs532191081; called by muse, varscan2
- IGLV3-1 | c.88T>G p.S30A | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as rs535075254; called by muse, varscan2
- IGLV3-1 | c.181T>C p.S61P | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs762596366; called by muse, varscan2
- LYRM1 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 3/23 reads (13%) | catalogued as COSV54643792; called by muse, mutect2
- MAML3 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as rs774116209, COSV59070708; called by muse, mutect2, varscan2
- MAP3K6 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.29); PolyPhen benign (0.094); catalogued as rs751432601, COSV62890598; called by muse, mutect2, varscan2
- MUC4 | c.12664G>A p.A4222T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.537); catalogued as rs11915935; called by muse, varscan2
- PAWR | c.656C>A p.P219H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.351); catalogued as COSV60923302; called by muse, mutect2, varscan2
- ZFP36L2 | c.931_939del p.A311_S313del | In Frame Del (DEL) | VAF 6/11 reads (55%) | catalogued as rs747450771; called by mutect2, varscan2
- ZNF385D | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.134); catalogued as rs777345108, COSV55757190; called by muse, mutect2, varscan2
- APOB | c.12061A>G p.K4021E | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCRL2 | c.981dup p.Q328Afs*12 | Frame Shift Ins (INS) | VAF 34/60 reads (57%) | called by mutect2, pindel, varscan2
- CFAP61 | c.1418_1430del p.D473Gfs*10 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | called by mutect2, pindel, varscan2
- CMYA5 | c.2771A>T p.N924I | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.077); called by muse, mutect2
- CRYBG2 | c.274A>C p.S92R | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ESF1 | c.1139T>A p.F380Y | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- FAM217B | c.964C>A p.H322N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FAM234B | c.1324T>A p.L442I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- IQGAP2 | c.1799G>T p.W600L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); called by muse, mutect2
- LRRC10 | c.791A>G p.E264G | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- OR4C11 | c.632T>A p.I211N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- PARP10 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- RBM15 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- STARD7 | c.889G>C p.V297L | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.526); called by muse, mutect2
- TRMT61B | c.1036T>C p.F346L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0.001); called by muse, mutect2
- APOL2 | c.822C>T p.I274= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs376116463; called by muse, mutect2
- CADPS | c.2772G>A p.T924= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs188157614, COSV51883297; called by muse, mutect2, varscan2
- CR1 | c.2730C>T p.F910= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs758445228; called by muse, mutect2, varscan2
- DLGAP4 | c.120C>T p.F40= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs528736011, COSV59415014; called by muse, mutect2, varscan2
- IGHV2-70D | c.168C>T p.S56= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs1233195687; called by muse, varscan2
- IGKV4-1 | c.231A>G p.A77= | Silent (SNP) | VAF 12/17 reads (71%) | catalogued as rs370136761; called by muse, mutect2, varscan2
- L3MBTL3 | c.870T>C p.C290= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV62387863; called by muse, mutect2, varscan2
- MIEF2 | c.1078C>T p.L360= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV59902037; called by muse, mutect2
- MKI67 | c.2517A>T p.G839= | Silent (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- PCDH10 | c.1257C>T p.A419= | Silent (SNP) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- PPIL4 | c.12A>G p.L4= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs373364423; called by muse, mutect2, varscan2
- TRPM5 | c.3363C>T p.D1121= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs148001795; called by muse, mutect2, varscan2
- UBR1 | c.222G>T p.L74= | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2
- AC073107.1 | n.344+2218A>G | Intron (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- B3GALT5-AS1 | n.858C>T | RNA (SNP) | VAF 21/38 reads (55%) | called by muse, mutect2, varscan2
- BRWD1 | c.*1122A>T | 3'UTR (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- C8orf31 | n.539-421G>C | Intron (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- CDC5L | c.*1870C>T | 3'UTR (SNP) | VAF 13/30 reads (43%) | catalogued as rs1017444985; called by muse, mutect2, varscan2
- CHI3L2 | c.-734A>C | 5'UTR (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- DDX1 | chr2:15591537 C>T | 5'Flank (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- EIF4A2 | c.208+132G>T | Intron (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- EPGN | c.407+87C>G | Intron (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- HOATZ | c.226+74C>G | Intron (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2
- HPRT1 | c.-36C>T | 5'UTR (SNP) | VAF 5/7 reads (71%) | catalogued as rs1166722526; called by muse, mutect2
- KRT77 | c.*535C>G | 3'UTR (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- LCOR | c.*2486del | 3'UTR (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel
- LUZP2 | c.*444C>T | 3'UTR (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-10496G>T | Intron (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- MEG3 | chr14:100860697 C>T | 3'Flank (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2, varscan2
- MIR411 | n.17A>G | RNA (SNP) | VAF 3/11 reads (27%) | catalogued as rs1165649618; called by muse, mutect2
- MIR5195 | chr14:106851212 T>C | 5'Flank (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- MPPED2 | c.*1167C>A | 3'UTR (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- MPPED2 | c.*1166G>A | 3'UTR (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- MTMR3 | c.3425+32G>A | Intron (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- NRXN1 | c.832+3820A>C | Intron (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- NSG1 | c.*466G>C | 3'UTR (SNP) | VAF 2/18 reads (11%) | called by muse, mutect2
- NTF3 | c.*144dup | 3'UTR (INS) | VAF 8/28 reads (29%) | called by pindel, varscan2
- NTRK2 | c.1585+7927T>C | Intron (SNP) | VAF 9/19 reads (47%) | catalogued as rs199542465; called by muse, mutect2, varscan2
- OARD1 | c.*535G>A | 3'UTR (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- OBSCN | c.988+87C>T | Intron (SNP) | VAF 5/35 reads (14%) | catalogued as rs893935741; called by muse, mutect2, varscan2
- PAPPA | c.*4249T>A | 3'UTR (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- PPARGC1B | c.*5185G>T | 3'UTR (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- RABEP2 | c.62-10T>A | Intron (SNP) | VAF 4/24 reads (17%) | called by muse, varscan2
- RC3H2 | c.*2276C>T | 3'UTR (SNP) | VAF 8/10 reads (80%) | catalogued as rs971597520; called by muse, mutect2
- RN7SL484P | n.36C>T | RNA (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2
- ROBO3 | c.161-308G>A | Intron (SNP) | VAF 11/25 reads (44%) | catalogued as rs1487485616; called by muse, mutect2, varscan2
- SH3BGRL | c.-47C>T | 5'UTR (SNP) | VAF 6/8 reads (75%) | called by muse, mutect2
- SHTN1 | c.*318A>G | 3'UTR (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- SMAD4 | c.*4281C>G | 3'UTR (SNP) | VAF 9/30 reads (30%) | catalogued as rs1211081289; called by muse, mutect2, varscan2
- TXNRD1 | c.414+1988T>C | Intron (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2
- UNC79 | chr14:93707295 A>G | 3'Flank (SNP) | VAF 17/28 reads (61%) | called by muse, mutect2, varscan2
- VPS37A | c.126-117T>C | Intron (SNP) | VAF 8/21 reads (38%) | catalogued as rs781268834; called by muse, mutect2, varscan2
- YIPF4 | c.*6215A>G | 3'UTR (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- ZNF638 | c.3261+419C>T | Intron (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- ZNF721 | c.*1231A>G | 3'UTR (SNP) | VAF 5/15 reads (33%) | catalogued as rs1441637294; called by muse, mutect2, varscan2
